Somatic mutation profile of tumor specimen TARGET-40-PAVXDP-01A (aliquot TARGET-40-PAVXDP-01A-01D) from TARGET case TARGET-40-PAVXDP, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 17.7 years (6,447 days).
Specimen TARGET-40-PAVXDP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4dca2ac9-9653-4dc4-9b76-ccba5c6a012f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAVXDP-10A (Blood Derived Normal), aliquot TARGET-40-PAVXDP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/924d21ba-f636-46f5-849c-de8bfafc44da

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.398T>A p.M133K | Missense Mutation (SNP) | VAF 65/94 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.061); catalogued as CM910373, CM973400, COSV52744834, COSV52795528, COSV52821486, COSV52852024; called by muse, mutect2, varscan2
- SSRP1 | c.1740G>T p.K580N | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53480772; called by muse, mutect2, varscan2
- TTN | c.12283C>A p.P4095T (on ENST00000591111; = p.P4049T on NM_003319.4) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as rs1279181718; called by muse, mutect2, varscan2
- ANO2 | c.1130G>A p.G377E (on ENST00000356134 / NM_001278597.3; = p.G381E on NM_001278596.3) | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.69243C>G p.F23081L (on ENST00000591111; = p.F15657L on NM_003319.4) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZIC2 | c.891G>C p.Q297H | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.094); called by muse, mutect2
- FLT3 | c.243G>A p.V81= | Silent (SNP) | VAF 23/38 reads (61%) | called by muse, mutect2, varscan2
